Somatic mutation profile of tumor specimen TCGA-77-A5GA-01A (aliquot TCGA-77-A5GA-01A-11D-A27K-08) from TCGA case TCGA-77-A5GA, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.0 years (27,762 days).
Specimen TCGA-77-A5GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c0278a6-b2a4-4b1e-a3e7-0d4f8b5774e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5GA-10A (Blood Derived Normal), aliquot TCGA-77-A5GA-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27fe1df2-9e6a-4623-9a63-263c7e66a410

The open-access MAF lists 163 somatic variants for this specimen: 129 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 28, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 4, Splice Region 3, Intron 2, 3'UTR 1, 5'UTR 1, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1386C>A p.D462E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV101037258; called by muse, mutect2, varscan2
- ADAMTS12 | c.635-2A>T p.X212_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100711265; called by muse, mutect2, varscan2
- ADIPOR1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100579573; called by muse, mutect2, varscan2
- ALDH3A1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855964; called by muse, mutect2, varscan2
- AMER1 | c.2243A>T p.Y748F | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV100366614; called by muse, mutect2, varscan2
- ASAP1 | c.1168+1G>C p.X390_splice | Splice Site (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100727460; called by muse, varscan2
- ATG10 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as rs909484260, COSV99967028; called by muse, mutect2, varscan2
- BMP2K | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100621820; called by muse, mutect2, varscan2
- CACNA1B | c.3546T>A p.A1182= | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99498286; called by muse, mutect2, varscan2
- CAND1 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV101607331; called by muse, mutect2, varscan2
- CCDC102B | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100103939, COSV60151170; called by muse, mutect2, varscan2
- CCDC115 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs772966334, COSV99383777; called by muse, mutect2, varscan2
- CCDC57 | c.2485A>T p.T829S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs996405601, COSV101051948, COSV66438028; called by muse, mutect2, varscan2
- CDC42BPB | c.4891C>G p.P1631A | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100775506; called by muse, mutect2, varscan2
- CFAP74 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs766330644; called by muse, mutect2
- CLCA2 | c.2624A>T p.Q875L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100991600; called by muse, mutect2, varscan2
- CNOT8 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV53585073, COSV99597211; called by muse, mutect2, varscan2
- CNTNAP5 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV101443753, COSV99081547; called by muse, mutect2, varscan2
- CNTNAP5 | c.2130G>T p.W710C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101443754; called by muse, mutect2, varscan2
- CRTAM | c.198A>T p.L66F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs367891560; called by muse, mutect2, varscan2
- CSMD3 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV52167613, COSV99820440; called by muse, mutect2, varscan2
- CUBN | c.387+2T>G p.X129_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100910613; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CUL2 | c.618T>G p.I206M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs1342280007, COSV101039203; called by muse, mutect2, varscan2
- CYP20A1 | c.899A>T p.K300I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100619077; called by muse, mutect2, varscan2
- DDX50 | c.1576A>T p.K526* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101007265; called by muse, mutect2, varscan2
- DENND4A | c.5365A>C p.K1789Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV101475377; called by muse, mutect2
- DHCR24 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100987820; called by muse, mutect2, varscan2
- DIDO1 | c.5396G>C p.R1799T | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV56630472, COSV99826309; called by muse, mutect2, varscan2
- ENTPD7 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as COSV100978446; called by muse, mutect2
- EYS | c.630C>A p.Y210* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100676733; called by muse, mutect2
- FAP | c.1968C>T p.Y656= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs201719538; called by muse, mutect2, varscan2
- FGL2 | c.398T>G p.L133* | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99592785; called by muse, mutect2, varscan2
- FNDC7 | c.2132T>C p.I711T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as rs761918620, COSV99601394; called by muse, mutect2, varscan2
- FSHB | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99569464; called by muse, mutect2, varscan2
- GALNT14 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205035; called by muse, mutect2, varscan2
- GRIK1 | c.833C>A p.T278N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100517226; called by muse, mutect2, varscan2
- GTF2B | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100980548; called by muse, mutect2, varscan2
- GYG1 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.085); catalogued as COSV99936886; called by muse, mutect2
- H4C5 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100748014; called by muse, mutect2
- HAPLN1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99165030; called by muse, mutect2, varscan2
- HECW2 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV99647691; called by muse, mutect2, varscan2
- HOXB9 | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100239555; called by muse, mutect2, varscan2
- HTR5A | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs753686247, COSV55282057, COSV55283700; called by muse, mutect2, varscan2
- ICAM3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50328660; called by muse, varscan2
- IGHV1-45 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782689013; called by muse, mutect2, varscan2
- IGKV5-2 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs374904672; called by muse, mutect2, varscan2
- KCNG1 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100857124; called by muse, mutect2, varscan2
- KCNJ15 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs953962349, COSV100154275; called by muse, mutect2
- LRFN2 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs866865355, COSV57830818; called by muse, mutect2, varscan2
- LRFN2 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599681; called by muse, mutect2, varscan2
- LRRTM4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV69138907; called by muse, mutect2, varscan2
- MKRN3 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV100091337; called by muse, mutect2, varscan2
- MMP10 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666338; called by muse, mutect2, varscan2
- MMP12 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV100404997, COSV58259971; called by muse, mutect2, varscan2
- MON1B | c.1446G>T p.V482= | Splice Region (SNP) | VAF 144/493 reads (29%) | catalogued as COSV99941777; called by muse, mutect2, varscan2
- MRPL28 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV99170711; called by muse, mutect2, varscan2
- MYO16 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99194115; called by muse, mutect2, varscan2
- MYO1B | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs1030911011, COSV100269441; called by muse, mutect2
- NAALAD2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58963766; called by muse, mutect2
- NEB | c.13239G>C p.K4413N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99424855; called by muse, mutect2, varscan2
- NELFB | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs539723050, COSV100546955; called by muse, mutect2, varscan2
- NISCH | c.93+1G>A p.X31_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as rs764491234, COSV99234778; called by muse, mutect2, varscan2
- OBI1 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758842862, COSV99932422; called by muse, mutect2, varscan2
- OCRL | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 138/216 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV63980626, COSV63982292; called by muse, mutect2, varscan2
- OR10X1 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100936683, COSV63768016; called by muse, mutect2
- OR13A1 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); catalogued as COSV100981055; called by muse, mutect2, varscan2
- OR2M3 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101513414; called by muse, mutect2, varscan2
- OR4C12 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58859951; called by muse, mutect2, varscan2
- OR4M1 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as COSV100271311; called by muse, mutect2, varscan2
- OR5K3 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051657; called by muse, mutect2, varscan2
- OR5R1 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100393504; called by muse, mutect2, varscan2
- OR5W2 | c.627T>A p.S209R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100747664; called by muse, mutect2, varscan2
- OR8D4 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV100361772, COSV100361856; called by muse, mutect2
- OR8D4 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV100361857; called by muse, mutect2
- P2RY8 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV101184088; called by muse, mutect2
- PAK3 | c.901C>G p.L301V (on ENST00000262836 / NM_001324328.2; = p.L286V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99457710; called by muse, mutect2, varscan2
- PCDHA9 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.517); catalogued as rs199785183, COSV100969775, COSV65325224; called by muse, mutect2, varscan2
- PCDHGB4 | c.1670del p.A557Gfs*30 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as COSV53940277; called by mutect2, pindel, varscan2
- PCOLCE2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930793; called by muse, mutect2
- PER3 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100728389; called by muse, mutect2, varscan2
- PHKA2 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV101177220; called by muse, mutect2, varscan2
- PKHD1L1 | c.3394G>T p.A1132S | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.173); catalogued as COSV101006464; called by muse, mutect2, varscan2
- POGK | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100902516; called by muse, mutect2, varscan2
- PREX1 | c.4729G>C p.A1577P | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV100906536; called by muse, mutect2, varscan2
- PRUNE2 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750435485, COSV65041566, COSV65046361; called by muse, varscan2
- PSMD3 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs775613009, COSV99227905; called by muse, mutect2, varscan2
- RABGGTB | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54204072, COSV99591988; called by muse, mutect2, varscan2
- RPS16 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as rs978379199, COSV99261845; called by muse, mutect2
- RUVBL1 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100494222; called by muse, mutect2, varscan2
- SAMD3 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100931818; called by muse, varscan2
- SIN3A | c.2830C>G p.Q944E | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100845175; called by muse, mutect2, varscan2
- SLC25A3 | c.766G>A p.E256K (on ENST00000228318 / NM_005888.3; = p.E255K on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99499329; called by muse, mutect2, varscan2
- SLC27A6 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99323066; called by muse, mutect2, varscan2
- SLC4A7 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.791); catalogued as rs768592781, COSV55404587; called by muse, mutect2, varscan2
- SLIT2 | c.1437del p.A480Lfs*17 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as COSV56586791; called by mutect2, pindel, varscan2
- SLTM | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99989252; called by muse, mutect2, varscan2
- SMS | c.210G>T p.L70F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV101048125; called by muse, mutect2, varscan2
- SPATA9 | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99174159; called by muse, mutect2, varscan2
- SPEF2 | c.4018A>G p.R1340G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100607906; called by muse, mutect2, varscan2
- SPTAN1 | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV100823733; called by muse, mutect2, varscan2
- SPTAN1 | c.2012-1G>T p.X671_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100823735; called by muse, mutect2, varscan2
- SPTAN1 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100823737; called by muse, mutect2, varscan2
- SPTAN1 | c.2142G>C p.Q714H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100823738; called by muse, mutect2, varscan2
- SSH2 | c.1655A>G p.N552S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs138829419; called by muse, mutect2, varscan2
- TAAR5 | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99236931; called by muse, mutect2, varscan2
- TENM3 | c.1748T>C p.I583T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101305227; called by muse, mutect2, varscan2
- TET1 | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1241056232, COSV65389486; called by muse, mutect2, varscan2
- TMEM168 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100454675; called by muse, mutect2, varscan2
- TRPV3 | c.1479G>A p.W493* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100027889; called by muse, mutect2, varscan2
- TTN | c.88463C>A p.S29488Y (on ENST00000591111; = p.S22064Y on NM_003319.4) | Missense Mutation (SNP) | VAF 44/236 reads (19%) | PolyPhen possibly damaging (0.667); catalogued as COSV100619216, COSV100625269; called by muse, mutect2, varscan2
- UBXN10 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1187611365, COSV100907761, COSV66771876; called by muse, mutect2
- USP25 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53484520; called by muse, mutect2, varscan2
- XKR7 | c.888C>A p.Y296* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV101629271; called by muse, mutect2, varscan2
- ZMYM4 | c.3595T>G p.S1199A | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); catalogued as COSV100110808; called by muse, mutect2, varscan2
- ZNF135 | c.382G>A p.D128N (on ENST00000313434 / NM_001289401.2; = p.D140N on NM_003436.4) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100536684; called by muse, mutect2
- ZNF135 | c.499G>T p.E167* (on ENST00000313434 / NM_001289401.2; = p.E179* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100536686; called by muse, mutect2
- ZNF135 | c.1807G>A p.E603K (on ENST00000313434 / NM_001289401.2; = p.E615K on NM_003436.4) | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100536545; called by muse, mutect2, varscan2
- ZNF232 | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100005726; called by muse, mutect2
- ZNF670 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs774202778, COSV100829294; called by muse, mutect2, varscan2
- ZNF785 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101235725; called by muse, mutect2, varscan2
- ZPLD1 | c.587C>T p.S196L (on ENST00000466937 / NM_001329788.1; = p.S212L on NM_175056.2) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as COSV100083344, COSV60353946; called by muse, mutect2, varscan2
- HELT | c.679del p.H227Tfs*? | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-64 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGKV1D-16 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52N5 | c.367del p.V123Cfs*7 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- PCDHA10 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.1871G>T p.W624L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA4 | c.255C>A p.P85= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs369987407, COSV100933164; called by mutect2, varscan2
- ABCC11 | c.1734C>T p.P578= | Silent (SNP) | VAF 40/280 reads (14%) | catalogued as COSV62323358; called by muse, mutect2, varscan2
- ABCG8 | c.1647C>T p.A549= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs369736263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAD1 | c.75A>T p.P25= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99635656; called by muse, mutect2, varscan2
- ATRX | c.3402G>A p.L1134= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV100971080; called by muse, mutect2, varscan2
- CDH11 | c.2349A>C p.A783= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV99218958; called by muse, mutect2, varscan2
- CFAP54 | c.7977T>C p.A2659= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100733264; called by muse, mutect2, varscan2
- DOK6 | c.213G>C p.L71= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101234607; called by muse, mutect2, varscan2
- EPPK1 | c.2160G>T p.L720= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV101599885; called by muse, mutect2, varscan2
- FUS | c.1092C>A p.I364= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99568776; called by muse, mutect2, varscan2
- ITGA8 | c.1056C>T p.S352= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1037227341, COSV100959390; called by muse, mutect2
- LRP1B | c.6936C>A p.I2312= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV101257932, COSV101257970; called by muse, mutect2, varscan2
- MYPN | c.1962C>A p.A654= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100590215; called by muse, mutect2
- NAV1 | c.2052G>T p.V684= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV99819116; called by muse, varscan2
- OR6Q1 | c.513A>G p.T171= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs765312411, COSV100110152; called by muse, mutect2, varscan2
- PCNX2 | c.801A>G p.L267= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs909405990, COSV99268386; called by muse, mutect2, varscan2
- PPARG | c.453T>C p.Y151= (on ENST00000287820 / NM_015869.5; = p.Y121= on NM_005037.7) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99826597; called by muse, mutect2, varscan2
- PTPRJ | c.1653C>T p.V551= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs946462335, COSV101395406, COSV69252758; called by muse, mutect2
- RFX4 | c.577C>T p.L193= (on ENST00000392842 / NM_213594.3; = p.L99= on NM_032491.6) | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV99986050; called by muse, mutect2, varscan2
- SLCO1A2 | c.405T>C p.N135= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100262210; called by muse, mutect2, varscan2
- SMC1B | c.714G>T p.L238= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100663331; called by muse, mutect2, varscan2
- TESPA1 | c.1380C>G p.T460= (on ENST00000316577 / NM_001098815.3; = p.T322= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 46/221 reads (21%) | catalogued as COSV100345359; called by muse, mutect2, varscan2
- TNN | c.471C>T p.C157= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99512315; called by muse, mutect2
- TTN | c.62850A>G p.L20950= (on ENST00000591111; = p.L13526= on NM_003319.4) | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1479846494, COSV100619217; called by muse, mutect2, varscan2
- UTS2B | c.99C>A p.T33= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100484270; called by muse, mutect2
- ZFHX4 | c.6309C>T p.D2103= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs781387338, COSV50490459; called by muse, mutect2
- ZIC1 | c.1203C>T p.Y401= | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as COSV51557215; called by muse, mutect2
- ZNF451 | c.2766T>C p.N922= (on ENST00000370706 / NM_001031623.3; = p.N874= on NM_015555.2) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1409028658, COSV100674963; called by muse, mutect2, varscan2
- EI24P4 | n.905A>T | RNA (SNP) | VAF 61/322 reads (19%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95533438 C>A | 5'Flank (SNP) | VAF 39/210 reads (19%) | called by muse, mutect2, varscan2
- RAPH1 | c.733-8388C>T | Intron (SNP) | VAF 14/91 reads (15%) | catalogued as rs1393517175, COSV100051653; called by muse, mutect2, varscan2
- RPL23A | c.26-134A>G | Intron (SNP) | VAF 42/111 reads (38%) | catalogued as rs1465077203, COSV99411802; called by muse, mutect2, varscan2
- SDHC | c.*76C>T | 3'UTR (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100713707; called by muse, mutect2
- WDR92 | c.-84G>T | 5'UTR (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99718378; called by muse, mutect2, varscan2
